TCGA case TCGA-AF-3911 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17e286b7-7793-446d-b556-1108addb5ba2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 48.2 years (17,609 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,148 days (3.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 9; Lymph nodes tested: 18; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 68 days; Days to treatment end: 106 days; Number of cycles: 6; Treatment dose: 13,271 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 68 days; Days to treatment end: 107 days; Treatment dose: 5,040 cGy; Course number: 1; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 145 days; Days to treatment end: 302 days; Number of cycles: 12; Treatment dose: 61,776 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 145 days; Days to treatment end: 300 days; Number of cycles: 12; Treatment dose: 10,296 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 145 days; Days to treatment end: 300 days; Number of cycles: 12; Treatment dose: 6,200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 145 days; Days to treatment end: 285 days; Number of cycles: 11; Treatment dose: 1,868 mg; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 50.1 years (18,304 days); Days to diagnosis: 695 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 51.0 years (18,629 days); Days to diagnosis: 1,020 days (2.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.

Follow-up (5 entries)
- Days to follow up: 537 days (1.5 years); Disease response: Tumor Free.
- Day 695 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 761 days (2.1 years); Disease response: With Tumor.
- Day 1,020 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,148 days (3.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 1.1 ng/mL.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 94.5 kg; Height: 180.3 cm; BMI: 29.1.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AF-3911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-AF-3911-01A-01-BS1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 50; Percent normal cells: 70; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-AF-3911-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 75; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-AF-3911-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AF-3911-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 1.1; Lymphovascular invasion indicator: Yes; Microsatellite instability: No; Loci tested count: 5; Loci abnormal count: 0; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 2; Pharmaceutical therapy drug name: 5FU.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 5: Regimen number: 1; Pharmaceutical therapy drug name: 5FU.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 3, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,148 days; disease-specific survival: no event (censored), 1,148 days; disease-free interval: event (new tumor event after initially disease-free), 695 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 695 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AF-3911-01A-01D-1732-01): tumor purity 0.72, ploidy 3.18, whole-genome doublings 1.
